Somatic mutation profile of tumor specimen 0DLFBI from CCDI case PBBZGW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 0.9 years (314 days).
Specimen 0DLFBI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c598cdd2-7331-4957-95ca-bf9c872d7542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLFAZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5808cef3-99ca-4924-b31d-a04eb8186e28

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 33/928 reads (4%) | catalogued as COSV59989381; called by muse, mutect2
- DMPK | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as rs1304768977; called by muse, mutect2
- RB1 | c.289del p.E97Nfs*14 | Frame Shift Del (DEL) | VAF 266/653 reads (41%) | catalogued as CD931046; called by mutect2, varscan2
- TRAF6 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 446/1071 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1418393714, COSV61923205; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 52/1476 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 42/1456 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- ZNF462 | c.105T>A p.D35E | Missense Mutation (SNP) | VAF 54/1184 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.232); called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
